Surgical pathology report (de-identified scan), TCGA case TCGA-S9-A6WH, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Dept of Neurosurgery at University of Heidelberg, specimen TCGA-S9-A6WH-01A (Primary Tumor).

Neuropathology

Patient:

B-Day:

Patho-No.:

Commentary:

Histology and morphology correspond to oligastrocytoma WHO grade II.

Diagnosis:

Oligoastrocytoma WHO grade II

ICD-O-3
Oligoastrocytoma, grade II
9382/3
Site: Brain, supratentorial, NOS
C71.0
JW 8/12/13

Untranslated full report is
housed at the BCR

Criteria	No.
Aggravous Discrepancy	✓
Prior Biopsy History	✓

Source: NCI Genomic Data Commons file d8f9742e-b05e-4d53-aa54-d305e2ab0910 (TCGA-S9-A6WH.ED9DEB9C-4DC6-4743-8402-2CF3B0D171B3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).